Gene-level copy-number profile of tumor specimen TCGA-AA-3660-01A from TCGA case TCGA-AA-3660, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 51.8 years (18,932 days).
Specimen TCGA-AA-3660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.412a949c-326b-43cc-9753-87dcda33160c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3660-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d40eae96-f53e-4b40-9b29-e482b6f1062a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,989; copy number 2: 36,445; copy number 3: 15,845; copy number 4: 603; copy number 5: 739; copy number 6: 1,061; copy number 7: 132.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3660-01A-01D-1717-01): tumor purity 0.76, ploidy 2.33, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,573,767–6,577,359, 1 gene: AC007223.1.
- chr20:14,884,250–15,021,659, 3 genes: MACROD2-AS1, AL138808.1, RNU6-1159P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,932 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:66,432,486–66,518,524, 1 gene, copy number 5 (within-gene range 3–5): AC009879.3.
- chr8:66,480,648–145,066,685, 1,232 genes, copy number 5–6 (broad region; genes not listed).
- chr12:66,767–5,244,199, 131 genes, copy number 7 (broad region; genes not listed).
- chr12:5,315,961–5,319,347, 1 gene, copy number 7: AC006206.1.
- chr20:42,685,404–64,313,132, 567 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,977. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
